CCDI case PBBSJS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/37e2c452-f4e0-497f-8226-30ca45c0642c

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.7 years (3,891 days).

Biospecimens (3 samples)
- Sample 0DFPUA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFPUV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DFPV5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
